Somatic mutation profile of tumor specimen TCGA-DU-A6S6-01A (aliquot TCGA-DU-A6S6-01A-21D-A32B-08) from TCGA case TCGA-DU-A6S6, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.1 years (12,809 days).
Specimen TCGA-DU-A6S6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4619993-f43e-4b72-82d0-f3570c371e62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A6S6-10A (Blood Derived Normal), aliquot TCGA-DU-A6S6-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1611529e-832b-459d-b3f4-931da71ca6e4

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Frame Shift Del 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM23 | c.956A>T p.H319L | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV100008868; called by muse, mutect2, varscan2
- AKAP14 | c.187A>T p.K63* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV100538422; called by muse, mutect2, varscan2
- CENPJ | c.2756A>C p.K919T | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV101121580; called by muse, mutect2, varscan2
- DPPA3 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 98/168 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1384240409, COSV61503509; called by muse, mutect2, varscan2
- INPPL1 | c.3617G>A p.R1206Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs772149044, COSV99996661; called by muse, mutect2, varscan2
- PC | c.1936del p.A646Pfs*102 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as rs776366810; called by mutect2, pindel, varscan2
- PTCD3 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.851); catalogued as COSV99606663; called by muse, mutect2, varscan2
- SLC17A4 | c.641T>A p.I214N | Missense Mutation (SNP) | VAF 109/225 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.385); catalogued as COSV100930675; called by muse, mutect2, varscan2
- TRIM71 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs373995975; called by muse, mutect2, varscan2
- VANGL2 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765036390, COSV63604223; called by muse, varscan2
- NLRP12 | c.435G>A p.A145= | Silent (SNP) | VAF 42/55 reads (76%) | catalogued as rs1423751053, COSV100145930, COSV60743750; called by muse, mutect2, varscan2
